Somatic mutation profile of tumor specimen TCGA-DX-A8BX-01A (aliquot TCGA-DX-A8BX-01A-11D-A37C-09) from TCGA case TCGA-DX-A8BX, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 52.9 years (19,339 days).
Specimen TCGA-DX-A8BX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 323f1e71-dfb2-482f-990b-5ddba995ab57.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A8BX-10A (Blood Derived Normal), aliquot TCGA-DX-A8BX-10A-01D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6cfbc2c0-28c8-4f77-abe5-f15d624cee71

The open-access MAF lists 79 somatic variants for this specimen: 49 protein-altering or splice-affecting, 26 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 26, RNA 3, Frame Shift Del 3, Nonsense Mutation 1, Frame Shift Ins 1, Splice Site 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1636C>A p.Q546K | Missense Mutation (SNP) | VAF 18/52 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as rs121913286, COSV55873527, COSV55882350; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARMC10 | c.1005G>T p.K335N | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs750973183, COSV100085741; called by mutect2, varscan2
- ASIP | c.14G>A p.R5H | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs145074053; called by muse, mutect2, varscan2
- AXL | c.1353G>C p.W451C (on ENST00000301178 / NM_021913.5; = p.W442C on NM_001699.6) | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.967); catalogued as COSV99996581; called by muse, mutect2, varscan2
- C2CD5 | c.933G>C p.L311F | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100448759; called by muse, mutect2, varscan2
- CARMIL3 | c.4081C>T p.P1361S | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.994); catalogued as rs757502071, COSV99393457; called by muse, mutect2, varscan2
- CCDC103 | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs763938078, COSV99492986; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC60 | c.778G>A p.G260S | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.287); catalogued as COSV100555121; called by muse, mutect2, varscan2
- CDH11 | c.1098C>A p.D366E | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99218470; called by muse, mutect2, varscan2
- CEMIP2 | c.751G>T p.G251C | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs139832017; called by muse, mutect2, varscan2
- CHD1 | c.716A>T p.N239I | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as COSV99399468; called by muse, mutect2, varscan2
- CHMP7 | c.853C>G p.L285V | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763408180, COSV100500592; called by muse, mutect2, varscan2
- CLDN10 | c.454G>A p.V152I | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV100176163; called by muse, mutect2, varscan2
- CSMD1 | c.1989G>T p.Q663H (on ENST00000520002; = p.Q662H on NM_033225.6) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.77); PolyPhen probably damaging (0.997); catalogued as COSV59318704; called by muse, mutect2, varscan2
- DDX5 | c.440_441+2del p.X147_splice | Splice Site (DEL) | VAF 8/23 reads (35%) | catalogued as rs782442161; called by mutect2, pindel, varscan2
- DST | c.4268A>C p.D1423A (on ENST00000361203 / NM_001374722.1; = p.D1097A on NM_001723.6) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as COSV99755732, COSV99756172; called by muse, mutect2, varscan2
- DYNC1H1 | c.10919G>C p.S3640T | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.11); catalogued as COSV100794917; called by muse, mutect2, varscan2
- DYNC1H1 | c.11570C>G p.S3857C | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.198); catalogued as COSV100794921; called by muse, varscan2
- DYNC1I1 | c.955G>C p.G319R | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100268405; called by muse, mutect2, varscan2
- EPHB1 | c.2006C>T p.A669V | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67662077; called by mutect2, varscan2
- EVI2A | c.533G>C p.R178T | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99907605; called by muse, mutect2, varscan2
- FGF23 | c.199C>T p.Q67* | Nonsense Mutation (SNP) | VAF 5/18 reads (28%) | catalogued as CM1412489, COSV52978050, COSV99426424; called by muse, mutect2, varscan2
- HOOK3 | c.2141C>T p.P714L | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as rs1047495131, COSV100294976; called by muse, mutect2, varscan2
- IL17B | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs528081511, COSV51002269; called by muse, mutect2, varscan2
- KAT7 | c.1525C>T p.R509C | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as rs769376467, COSV52014050; called by muse, varscan2
- KIAA1109 | c.3022G>C p.G1008R | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52674638, COSV99163729; called by muse, mutect2, varscan2
- KIAA1549L | c.2606C>T p.A869V (on ENST00000321505; = p.A1166V on NM_012194.3) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.8); catalogued as COSV99683535; called by muse, mutect2, varscan2
- KRTAP13-3 | c.338G>A p.G113E | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV61878969; called by muse, mutect2, varscan2
- MIP | c.379G>A p.V127M | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs767456401, COSV99234265; called by muse, mutect2, varscan2
- MISP | c.1135G>A p.D379N | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.105); catalogued as rs372474785; called by muse, mutect2, varscan2
- NADSYN1 | c.1489G>T p.A497S | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.258); catalogued as COSV100034761; called by muse, mutect2
- NALCN | c.1084G>T p.V362L | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as COSV99215289; called by muse, mutect2, varscan2
- OR2B11 | c.382G>A p.V128M | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as rs375546848; called by muse, mutect2, varscan2
- OR52A5 | c.398G>A p.R133K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); catalogued as COSV100263452, COSV56614865; called by muse, mutect2, varscan2
- PRPF6 | c.72C>T p.G24= | Splice Region (SNP) | VAF 13/44 reads (30%) | catalogued as rs774832670, COSV99412010; called by muse, mutect2, varscan2
- SCN2A | c.2383A>T p.N795Y | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV99331774; called by muse, mutect2, varscan2
- SPTA1 | c.706C>G p.Q236E | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100934986; called by muse, mutect2, varscan2
- TERT | c.2092C>T p.R698W | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs866282352, CM128081, COSV57204100, COSV99718422; called by muse, mutect2, varscan2
- TIGD7 | c.36G>T p.L12F | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99239877; called by muse, mutect2
- WDR7 | c.2436G>C p.L812F | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99589494; called by muse, mutect2, varscan2
- WNK2 | c.2527C>G p.L843V | Missense Mutation (SNP) | VAF 53/214 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as COSV99942480; called by muse, mutect2, varscan2
- ZC2HC1A | c.598G>T p.V200F | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.074); catalogued as COSV99804074; called by muse, mutect2, varscan2
- ZNF592 | c.1709C>T p.P570L | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100245877; called by muse, mutect2, varscan2
- GDF2 | c.697C>T p.H233Y | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KAT7 | c.1545_1546dup p.L516Rfs*3 | Frame Shift Ins (INS) | VAF 23/68 reads (34%) | called by pindel, varscan2
- KDM5A | c.797_798del p.R266Qfs*10 | Frame Shift Del (DEL) | VAF 9/36 reads (25%) | called by mutect2, pindel, varscan2
- LCAT | c.274C>A p.L92I | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); called by muse, mutect2
- PYROXD1 | c.44_53del p.V15Afs*24 | Frame Shift Del (DEL) | VAF 61/167 reads (37%) | called by mutect2, pindel, varscan2
- URGCP | c.480del p.A161Lfs*21 (on ENST00000453200 / NM_001077663.3; = p.A152Lfs*21 on NM_017920.4) | Frame Shift Del (DEL) | VAF 6/55 reads (11%) | called by mutect2, pindel*, varscan2*
- ALLC | c.1098C>T p.F366= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV99377849; called by mutect2, varscan2
- ANKRD13A | c.1050G>C p.P350= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV99923981; called by muse, mutect2, varscan2
- ATP6V0A2 | c.717G>A p.K239= | Silent (SNP) | VAF 7/82 reads (9%) | catalogued as rs1430085034, COSV100377017; called by muse, mutect2
- BLNK | c.43T>C p.L15= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV99813904; called by muse, mutect2, varscan2
- CAB39L | c.405C>T p.A135= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV100759560; called by muse, mutect2, varscan2
- CPZ | c.1215G>A p.T405= (on ENST00000360986 / NM_001014447.3; = p.T394= on NM_003652.3) | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as rs979783980, COSV59924994; called by muse, mutect2, varscan2
- CSMD1 | c.7341G>A p.R2447= (on ENST00000520002; = p.R2446= on NM_033225.6) | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV100148112; called by muse, mutect2, varscan2
- DNAJC6 | c.2259C>T p.N753= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs771875633, COSV54775119; called by muse, mutect2, varscan2
- DOLPP1 | c.135C>T p.V45= | Silent (SNP) | VAF 49/110 reads (45%) | catalogued as rs748554891, COSV100588426; called by muse, mutect2, varscan2
- DYNC1H1 | c.11454C>G p.L3818= | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as COSV100794919; called by muse, mutect2, varscan2
- DYNC1H1 | c.11487C>G p.L3829= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as COSV100794920; called by muse, varscan2
- H3C6 | c.354G>A p.V118= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as rs768528994, COSV100839024, COSV64519424; called by muse, mutect2, varscan2
- HIP1 | c.150G>A p.T50= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as rs372317584; called by muse, mutect2, varscan2
- IFT52 | c.1275C>T p.D425= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as COSV100887608; called by muse, mutect2, varscan2
- NECTIN2 | c.1017C>T p.R339= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as rs1169901675, COSV52975541; called by muse, mutect2, varscan2
- NXN | c.834C>T p.L278= | Silent (SNP) | VAF 77/171 reads (45%) | catalogued as rs193165884, COSV100403051, COSV100403157; called by muse, mutect2, varscan2
- OR2T35 | c.855C>A p.L285= | Silent (SNP) | VAF 7/23 reads (30%) | called by muse, mutect2, varscan2
- PCDHA8 | c.1374C>T p.P458= | Silent (SNP) | VAF 35/167 reads (21%) | catalogued as COSV65334968; called by muse, mutect2, varscan2
- PCLO | c.12588T>C p.I4196= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV100432922, COSV61666017; called by muse, mutect2, varscan2
- PLEC | c.8967C>T p.G2989= (on ENST00000322810 / NM_201380.4; = p.G2879= on NM_000445.5) | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as rs1370820771, COSV100514299; called by muse, mutect2, varscan2
- PMEL | c.303G>A p.Q101= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs760788630, COSV100657014, COSV62427592; called by muse, mutect2, varscan2
- PRKACG | c.720C>T p.Y240= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV55255016; called by muse, mutect2, varscan2
- SCN8A | c.2160G>A p.P720= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as rs967922373, COSV100633845; ClinVar: likely benign; called by muse, mutect2, varscan2
- TBX3 | c.1995G>A p.A665= (on ENST00000257566 / NM_016569.4; = p.A645= on NM_005996.4) | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs1226176985, COSV99983783; called by muse, mutect2, varscan2
- VN1R4 | c.408C>A p.I136= | Silent (SNP) | VAF 40/192 reads (21%) | catalogued as COSV100237427, COSV60805128; called by muse, mutect2, varscan2
- ZNF398 | c.382C>T p.L128= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV60067409; called by muse, mutect2, varscan2
- AL590867.2 | n.88G>A | RNA (SNP) | VAF 14/29 reads (48%) | catalogued as rs1251696299; called by muse, mutect2, varscan2
- KIR3DX1 | n.294G>A | RNA (SNP) | VAF 17/92 reads (18%) | catalogued as rs748771162, COSV99683174; called by muse, mutect2, varscan2
- SLC5A1 | chr22:32039580 A>G | 5'Flank (SNP) | VAF 24/76 reads (32%) | called by muse, mutect2, varscan2
- SNORD109A | n.6G>T | RNA (SNP) | VAF 17/58 reads (29%) | called by muse, mutect2, varscan2
